Somatic mutation profile of tumor specimen TCGA-2G-AAL5-01A (aliquot TCGA-2G-AAL5-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAL5, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 31.4 years (11,478 days).
Specimen TCGA-2G-AAL5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a46c00db-c20a-4ce9-a6b9-791a3b9b35b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAL5-10A (Blood Derived Normal), aliquot TCGA-2G-AAL5-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fcbb8aaf-717c-42a5-848b-379ebac7ad16

The open-access MAF lists 26 somatic variants for this specimen: 18 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 6, Frame Shift Del 3, In Frame Del 1, Nonsense Mutation 1, Splice Site 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6V0D1 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs529258503, COSV52098536; called by muse, mutect2, varscan2
- CNTN5 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201512506, COSV54276128; called by muse, mutect2, varscan2
- FAM126A | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as rs769843869; called by muse, mutect2, varscan2
- GNL3 | c.208_209del p.R70Afs*2 | Frame Shift Del (DEL) | VAF 55/240 reads (23%) | catalogued as rs761371320; called by pindel, varscan2
- LRRC8B | c.2215A>T p.N739Y | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs201504233; called by muse, mutect2, varscan2
- MUC4 | c.7727C>T p.P2576L | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.722); catalogued as rs1361683214; called by muse, varscan2
- SOX13 | c.1172G>T p.R391L | Missense Mutation (SNP) | VAF 79/129 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.1); catalogued as COSV65826189; called by muse, mutect2, varscan2
- ASTN1 | c.3214A>T p.K1072* | Nonsense Mutation (SNP) | VAF 40/159 reads (25%) | called by muse, mutect2, varscan2
- FLNA | c.5020G>C p.V1674L (on ENST00000369850 / NM_001110556.2; = p.V1666L on NM_001456.3) | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- GLT1D1 | c.1019T>C p.L340P (on ENST00000442111 / NM_001366889.1; = p.L260P on NM_144669.3) | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MERTK | c.1786+2T>C p.X596_splice | Splice Site (SNP) | VAF 40/152 reads (26%) | called by muse, mutect2, varscan2
- MTERF3 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- PAFAH1B1 | c.1219_1220del p.W407Gfs*21 | Frame Shift Del (DEL) | VAF 40/150 reads (27%) | called by pindel, varscan2
- PNMA8B | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAB12 | c.175A>T p.M59L | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SPACA1 | c.200C>A p.T67N | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- ZNF565 | c.1254_1262delinsG p.T419Sfs*11 (on ENST00000355114; = p.T379Sfs*11 on NM_152477.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 27/77 reads (35%) | called by pindel, varscan2*
- ZYG11A | c.1599_1601del p.F533del | In Frame Del (DEL) | VAF 34/137 reads (25%) | called by pindel, varscan2
- ATG2A | c.5487G>T p.L1829= | Silent (SNP) | VAF 26/58 reads (45%) | called by muse, mutect2, varscan2
- KANK1 | c.4023G>A p.T1341= | Silent (SNP) | VAF 50/115 reads (43%) | catalogued as rs148157700; ClinVar: likely benign; called by muse, mutect2, varscan2
- LAMA5 | c.9309C>T p.L3103= | Silent (SNP) | VAF 4/8 reads (50%) | called by muse, mutect2
- NT5DC4 | c.435C>T p.C145= | Silent (SNP) | VAF 38/109 reads (35%) | catalogued as rs1297554094; called by muse, mutect2, varscan2
- RITA1 | c.690G>A p.T230= | Silent (SNP) | VAF 30/106 reads (28%) | catalogued as rs747401205; called by muse, mutect2, varscan2
- TCOF1 | c.3033G>A p.Q1011= (on ENST00000377797 / NM_001135243.1; = p.Q934= on NM_000356.4) | Silent (SNP) | VAF 7/155 reads (5%) | catalogued as rs1268651096; called by muse, mutect2
- DNM2 | c.1336-1089C>G | Intron (SNP) | VAF 16/60 reads (27%) | catalogued as COSV100117123; called by muse, mutect2, varscan2
- PKD1L2 | n.375G>A | RNA (SNP) | VAF 29/60 reads (48%) | called by muse, mutect2, varscan2
